Somatic mutation profile of tumor specimen ALCH-AEG5-TTP1-A (aliquot ALCH-AEG5-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEG5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,341 days).
Specimen ALCH-AEG5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f62e71a7-6820-4775-b52d-dc9173bb9117.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEG5-NB1-A (Blood Derived Normal), aliquot ALCH-AEG5-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce494e5d-6327-41ef-9418-7b84089e9aa0

The open-access MAF lists 138 somatic variants for this specimen: 92 protein-altering or splice-affecting, 32 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 32, Splice Site 5, Nonsense Mutation 5, 5'UTR 4, Intron 4, 5'Flank 3, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2325+1G>T p.X775_splice | Splice Site (SNP) | VAF 31/372 reads (8%) | catalogued as rs1555613933, CS137211; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.2409+1G>T p.X803_splice | Splice Site (SNP) | VAF 16/164 reads (10%) | catalogued as rs1555614022, CS063343, CS073508, CS971824, COSV62196649; ClinVar: pathogenic; called by muse, mutect2
- ANKRD11 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56371332; called by muse, mutect2, varscan2
- APOB | c.9119C>T p.S3040L | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.092); catalogued as COSV51958956; called by muse, mutect2, varscan2
- C20orf144 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | catalogued as rs953438760; called by muse, mutect2
- CAPN6 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1001804980; called by muse, mutect2, varscan2
- CCKBR | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759134569; called by muse, mutect2, varscan2
- CRMP1 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771581090; called by muse, mutect2, varscan2
- DNAH7 | c.10318C>G p.P3440A | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56786565; called by muse, mutect2, varscan2
- DNAI4 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs956796361; called by muse, mutect2
- FSCB | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV61218660; called by muse, mutect2, varscan2
- HGH1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1459551986; called by muse, mutect2, varscan2
- HUWE1 | c.3292G>T p.A1098S | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as COSV53345535, COSV99472313; called by muse, mutect2
- KANSL1 | c.2719G>T p.E907* (on ENST00000574590 / NM_001193465.2; = p.E908* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | catalogued as COSV52273055; called by muse, mutect2, varscan2
- KRT38 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1325136989; called by muse, mutect2, varscan2
- MAGEE2 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64898179; called by muse, mutect2, varscan2
- MMRN1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); catalogued as COSV99306551; called by muse, mutect2, varscan2
- MYF6 | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV57353177; called by muse, mutect2, varscan2
- NDST4 | c.1646A>C p.Q549P | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as COSV52134249; called by muse, mutect2
- RNF213 | c.7981C>T p.Q2661* | Nonsense Mutation (SNP) | VAF 33/186 reads (18%) | catalogued as rs1294074039; called by muse, mutect2, varscan2
- SIDT2 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1345325131, COSV54055124; called by muse, mutect2
- SLC30A7 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1338600638; called by muse, mutect2
- SLC34A3 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1173522125, CM130956, COSV63187660; called by muse, mutect2
- SPTA1 | c.4338G>T p.Q1446H | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as COSV63761332; called by muse, mutect2
- URI1 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV56349534; called by muse, mutect2
- VAV1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV58384714; called by muse, mutect2
- ZEB2 | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.241); catalogued as COSV100356718, COSV57953987; called by muse, varscan2
- ZNF275 | c.58G>T p.V20F | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1404126272; called by muse, mutect2
- ACKR1 | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ANGPTL3 | c.1284G>T p.R428S | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- BCL11B | c.1591G>T p.E531* (on ENST00000357195 / NM_001282237.2; = p.E460* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- C2orf16 | c.2321T>C p.I774T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, varscan2
- C7 | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH23 | c.3711C>A p.D1237E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP250 | c.1305G>T p.Q435H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CLMN | c.645_646insT p.R216* | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- CNTNAP5 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- COL1A2 | c.1612-1G>A p.X538_splice | Splice Site (SNP) | VAF 24/426 reads (6%) | called by muse, mutect2
- COL4A1 | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- CSMD3 | c.9041G>T p.G3014V (on ENST00000297405 / NM_001363185.1; = p.G2845V on NM_052900.3) | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CYLC2 | c.276A>T p.L92F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP11B2 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DKC1 | c.1299A>T p.K433N | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK2 | c.314T>A p.L105H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DRD2 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- FAM193A | c.2708G>T p.R903L | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FAM83B | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- FMN2 | c.1325G>T p.R442M | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); called by muse, mutect2
- GRIN2A | c.4127G>T p.R1376L | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2
- HELZ2 | c.4582T>A p.Y1528N (on ENST00000467148 / NM_001037335.2; = p.Y959N on NM_033405.3) | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- HOPX | c.117G>T p.E39D (on ENST00000317745; = p.E57D on NM_032495.6) | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2
- HSPA1L | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLF9 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2
- KRT34 | c.41A>T p.K14I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- LGR5 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.267); called by muse, mutect2
- LRRC4C | c.944G>T p.W315L | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAPK9 | c.1232G>A p.S411N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.827); called by muse, varscan2
- MTA1 | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAPG | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NXPH2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2
- OR2T27 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51B2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); called by muse, mutect2
- PAPPA2 | c.5062C>A p.P1688T | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PCDHB7 | c.2302dup p.I768Nfs*23 | Frame Shift Ins (INS) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- PKD1L2 | c.2209A>T p.N737Y | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POTEJ | c.2290C>A p.H764N | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); called by muse, mutect2
- RAB41 | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- RANBP2 | c.7127A>T p.Q2376L | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RASA1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 22/129 reads (17%) | called by muse, varscan2
- RASAL2 | c.833A>T p.K278M | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM41 | c.638T>A p.F213Y | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- RELCH | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.143); called by muse, mutect2
- RIMBP2 | c.2798_2799del p.L933Qfs*29 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- SCN3A | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN3A | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3PXD2A | c.2810A>G p.N937S (on ENST00000369774 / NM_001365079.1; = p.N909S on NM_014631.2) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC19A3 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- SLC35F3 | c.1102G>T p.G368C (on ENST00000366617 / NM_001300845.1; = p.G437C on NM_173508.4) | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35G6 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC39A11 | c.901G>T p.A301S (on ENST00000542342 / NM_001159770.2; = p.A294S on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC39A12 | c.1804G>T p.A602S (on ENST00000377369 / NM_001145195.2; = p.A565S on NM_152725.3) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- SPTA1 | c.4338+1G>T p.X1446_splice | Splice Site (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- TAF1L | c.449T>A p.I150N | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TG | c.2759C>A p.T920K | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM30B | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TRIM9 | c.2010A>G p.I670M | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2
- TROAP | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBE2NL | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- WASH6P | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.101); called by muse, mutect2
- WDR64 | c.1292-10_1296del p.X431_splice | Splice Site (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- WNK1 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- XPO7 | c.367T>A p.C123S | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBEC3A | c.93C>A p.T31= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- ARHGAP40 | c.1176C>T p.L392= | Silent (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- C7 | c.1164T>A p.L388= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- CCDC115 | c.39G>T p.L13= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs1170627173; ClinVar: likely benign; called by muse, mutect2
- CCSER2 | c.1755G>A p.R585= | Silent (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- DAND5 | c.540C>A p.I180= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs200839356; called by mutect2, varscan2
- DTNA | c.405T>A p.A135= | Silent (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- FBXO30 | c.1110A>T p.V370= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- FSCB | c.873C>A p.V291= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV61219155; called by muse, mutect2, varscan2
- GLA | c.813C>T p.G271= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- H4C13 | c.210A>T p.A70= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- HEG1 | c.2241G>T p.L747= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- IL17F | c.201C>G p.R67= | Silent (SNP) | VAF 26/269 reads (10%) | called by muse, mutect2
- IL17REL | c.570G>A p.A190= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as COSV58008465; called by muse, mutect2
- ITGAD | c.2095C>A p.R699= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV66758844; called by muse, mutect2
- KRT14 | c.1077G>T p.L359= | Silent (SNP) | VAF 21/277 reads (8%) | called by muse, mutect2
- LMTK3 | c.1926G>A p.E642= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs769591534, COSV104373315, COSV54311389; called by mutect2, varscan2
- MAPK9 | c.1233C>T p.S411= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs1346110709; called by muse, mutect2, varscan2
- MRGPRX1 | c.573C>T p.L191= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as COSV57109564; called by muse, mutect2, varscan2
- MUC16 | c.25884C>A p.A8628= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- OLIG2 | c.573C>A p.G191= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- OR12D2 | c.687T>C p.S229= | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- PCDHB13 | c.78G>T p.A26= | Silent (SNP) | VAF 34/295 reads (12%) | catalogued as COSV53396357, COSV99507733; called by muse, mutect2, varscan2
- PCSK5 | c.2853C>T p.T951= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV70448627; called by muse, mutect2
- PIGM | c.165C>T p.F55= | Silent (SNP) | VAF 76/381 reads (20%) | called by muse, mutect2, varscan2
- PNMA8B | c.612C>A p.I204= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- POU5F2 | c.759G>T p.V253= | Silent (SNP) | VAF 26/233 reads (11%) | called by muse, mutect2, varscan2
- SLC5A8 | c.483T>C p.D161= | Silent (SNP) | VAF 34/373 reads (9%) | catalogued as rs1369615386; called by muse, mutect2
- SUGCT | c.123G>A p.L41= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- TNR | c.831C>A p.A277= | Silent (SNP) | VAF 49/264 reads (19%) | called by muse, mutect2, varscan2
- ZGPAT | c.489G>A p.A163= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as rs144182745; called by muse, mutect2
- ZHX2 | c.1131G>A p.V377= | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as COSV58714184; called by muse, mutect2, varscan2
- AC022748.1 | n.238C>T | RNA (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- CPLX2 | c.*93G>T | 3'UTR (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- DNAH17 | c.8511+2522G>T | Intron (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- ETDB | chrX:135123434 C>T | 5'Flank (SNP) | VAF 16/407 reads (4%) | catalogued as rs1471225128; called by muse, mutect2
- FGG | c.-5A>T | 5'UTR (SNP) | VAF 28/244 reads (11%) | called by muse, varscan2
- HELLS | c.1326+956G>T | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, varscan2
- KCNH1 | c.-1G>C | 5'UTR (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- MLXIP | c.*408C>T | 3'UTR (SNP) | VAF 8/186 reads (4%) | catalogued as rs369823539; called by muse, mutect2
- NEBL | c.-8G>T | 5'UTR (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- RYR2 | c.11146-1227C>A | Intron (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- SERGEF | c.1011+32716T>A | Intron (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- TIMM50 | chr19:39480801 C>A | 5'Flank (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- TTC27 | c.-46G>T | 5'UTR (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- VMA21 | chrX:151396958 G>T | 5'Flank (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
